Surgical pathology report (de-identified scan), TCGA case TCGA-Z7-A8R5, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site John Wayne Cancer Center, specimen TCGA-Z7-A8R5-01A (Primary Tumor).

[page 1 of 5]
ADDENDUM

Addendum #1

Entered:

BREAST CANCER PROGNOSTIC MARKERS

Specimen: Paraffin block 4E

Procedures: Paraffin Section Immunohistochemistry and DNA Flow Cytometry

ASSAYS: RANGES:	RESULTS:	FAVORABLE
Estrogen Receptors 3+)	POSITIVE, 3+	Positive (1 -
Progesterone Receptors 3+)	POSITIVE, TRACE TO 1+	Positive (1 -
Ploidy/DNA Index (DI) 1.0	ANEUPLOID, DI=1.6	Diploid, DI =
S-Phase Fraction (%) less)	NOT REPORTED DUE TO EXCESSIVE BACKGROUND	Low (3% or
Ki-67 (Proliferation marker) less)	INTERMEDIATE, 16%	Low (15% or
HER-2/neu (c-erb B2) 1+)	NEGATIVE (0)	Negative (0 -
p53	NEGATIVE, 0	Negative

These immunoperoxidase tests were developed and their performance characteristics determined by XXXXXXXXXXXXXXXXXXXXXXXXXXXXXXXXXXXX. Although not cleared or approved by the U.S. Food and Drug Administration, the FDA has determined that such clearance or approval is not necessary. These tests are used for clinical purposes and should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA) as qualified to perform high complexity clinical laboratory testing.

Addendum signed signature on file

ICD O-3
Carcinoma, unspecified lobular NOS
Site: 67 Breast NOS
8520/3
C50.9
7/5/30/14

[page 2 of 5]
GROSS DESCRIPTION

1. Labeled "blue node left axilla #1": The specimen consists of multiple possible lymph nodes ranging from 0.1 to 1.3 cm in greatest dimension. The lymph nodes are submitted entirely as follows: 1A - one possible lymph node bisected, 1B - remaining possible lymph nodes. Keratin ordered on both blocks.

2. Labeled "second blue node left axilla #2": The specimen consists of multiple possible lymph nodes ranging from 0.2 to 1.2 cm in greatest dimension. The lymph nodes are submitted entirely as follows: 2A - one possible lymph node bisected, 2B - remaining possible lymph nodes. Keratin ordered on both blocks.

3. Labeled "suspicious node left axilla": The specimen consists of a 2.0 x 1.3 x 0.2 cm pink firm possible lymph node. The lymph node is bisected and submitted entirely in 3A.

4. Labeled "segment left breast, long stitch - anterolateral, short stitch - anteromedial": The specimen consists of a 6.7 (medial to lateral) x 4.3 (anterior to posterior) x 2.1 cm portion of tan yellow to gray white fibrofatty breast tissue. The specimen is inked as follows: superior - blue, inferior - green, posterior - black, anterior - red. Sectioning reveals a 4.0 x 2.8 x 2.0 cm gray white focally hemorrhagic ill defined mass which extends up to the superior, posterior and inferior margins. The distance to the remaining margins is greater than 1.0 cm. The remaining cut surface features a large amount of fibrocystic change. A portion of the mass and normal tissue is submitted to XX for research (IRB# XXXXXXXXXXXXXXX). Representative sections are submitted from lateral to medial in 4A-J with en face margins in 4A and 4J. The mass is in 4C-H.

5. Labeled "additional segment left breast": The specimen consists of a 6.1 x 3.9 x 3.2 cm portion of tan yellow to gray white fibrofatty breast tissue. One aspect of the tissue is hemorrhagic and ragged while the opposing surface is smooth. The specimen is inked as follows: ragged surface - blue, smooth surface - black. Sectioning reveals multiple gray white gritty focally cystic suspicious areas which exude a yellow grumous material. The suspicious areas appear throughout the tissue and extend up to both margins. The majority of tissue to include closest margins are submitted in 5A-G.

6. Labeled "inferior margin left breast": The specimen consists of a 1.2 x 0.8 x 0.2 cm portion of tan yellow to gray white fibrofatty breast tissue. Submitted in toto in 6A.

7. Labeled "superior margin left breast": The specimen consists of a 1.2 x 0.6 x

[page 3 of 5]
0.2 cm
portion of tan yellow to gray white fibrofatty breast tissue. Submitted in toto in 7A.

8. Labeled "medial margin, left breast": The specimen consists of a 1.2 x 0.8 x 0.1 cm portion of tan yellow to gray white fibrofatty breast tissue. Submitted in toto in 8A.

9. Labeled "lateral margin, left breast": The specimen consists of a 1.3 x 0.5 x 0.3 cm portion of tan yellow to gray white fibrofatty breast tissue. Submitted in toto in 9A.

10. Labeled "anterior margin, left breast": The specimen consists of a 1.1 x 0.5 x 0.1 cm portion of tan yellow to gray white fibrofatty breast tissue. Submitted in toto in 10A.

11. Labeled "deep margin, left breast": The specimen consists of a 1.6 x 0.6 x 0.1 cm portion of tan yellow to gray white fibrofatty breast tissue. Submitted in toto in 11A.

Microscopic H&E stained sections are prepared and interpreted.

IMMUNOCYTOCHEMISTRY RESULTS

Block 1A, at 2 levels:
Keratin: Positive.

Block 1B, at 2 levels:
Keratin: Positive in one node.

Block 2A, at 2 levels:
Keratin: Positive.

Block 5B:
E-cadherin: Negative in infiltrating carcinoma and in most of ducts involved by in situ carcinoma, consistent with lobular carcinoma.

DIAGNOSIS

1. SENTINEL LYMPH NODES, LEFT AXILLA:
- METASTATIC CARCINOMA IN TWO OF THREE LYMPH NODES (2/3).
- METASTATIC DEPOSIT MEASURES 0.3 CM; NO EXTRACAPSULAR INVASION IDENTIFIED.
- IMMUNOHISTOCHEMICAL STAINS ARE CONFIRMATORY.
2. SENTINEL LYMPH NODES #2, LEFT AXILLA:
- METASTATIC CARCINOMA IN ONE OF ONE NODE (1/1).
- METASTATIC DEPOSIT MEASURES 1.0 CM; NO EXTRACAPSULAR INVASION IDENTIFIED.
- IMMUNOHISTOCHEMICAL STAINS ARE CONFIRMATORY.
3. LYMPH NODE, LEFT AXILLA, SUSPICIOUS:
- ONE NODE NEGATIVE FOR METASTATIC CARCINOMA (0/1).

[page 4 of 5]
- BENIGN CAPSULAR AND TRABECULAR NEVUS.
4. BREAST, LEFT, SEGMENTECTOMY:
- INFILTRATING LOBULAR CARCINOMA, CLASSIC PATTERN.
- TUMOR MEASURES APPROXIMATELY 5 CM IN GREATEST DIMENSION AND EXTENDS TO SUPERIOR, LATERAL, INFERIOR AND POSTERIOR SPECIMEN EDGES.
- LYMPHOVASCULAR INVASION IDENTIFIED.
- PLEASE SEE BREAST CANCER PROGNOSTIC SUMMARY BELOW.
5. BREAST, LEFT ADDITIONAL SEGMENT, SEGMENTECTOMY:
- INFILTRATING LOBULAR CARCINOMA INVOLVING MULTIPLE SPECIMEN EDGES (INCLUDING APPARENT OLD AND APPARENT NEW SPECIMEN EDGES).
- CARCINOMA EXTENDS THROUGH BULK OF THE TISSUE SEGMENT, MEASURING APPROXIMATELY 5.0 CM IN GREATEST DIMENSION.
- IN SITU CARCINOMA WITH DUCTAL INVOLVEMENT CONSISTENT WITH ANTEGRADE SPREAD OF LOBULAR CARCINOMA IN SITU.
- LYMPHOVASCULAR INVASION IDENTIFIED.
- ADDITIONAL FINDINGS: PROLIFERATIVE BREAST DISEASE WITH MICROCALCIFICATIONS.
6. BREAST, LEFT, INFERIOR MARGIN, BIOPSY:
- INFILTRATING LOBULAR CARCINOMA MEASURING 0.5 CM.
- SMALL FIBROADENOMA.
7. BREAST, LEFT, SUPERIOR MARGIN, BIOPSY:
- INFILTRATING LOBULAR CARCINOMA, MEASURING 0.25 CM.
8. BREAST, LEFT, MEDIAL MARGIN, BIOPSY:
- BENIGN BREAST TISSUE.
- NEGATIVE FOR MALIGNANCY.
9. BREAST, LEFT, LATERAL MARGIN, BIOPSY:
- INFILTRATING LOBULAR CARCINOMA, MEASURING APPROXIMATELY 1.2 CM.
- LOBULAR CARCINOMA IN SITU WITH EXTENSIVE DUCTAL INVOLVEMENT.
10. BREAST, LEFT, ANTERIOR MARGIN, BIOPSY:
- BENIGN BREAST TISSUE.
- NEGATIVE FOR MALIGNANCY.
11. BREAST, LEFT, DEEP MARGIN, BIOPSY:
- BENIGN FATTY BREAST TISSUE.
- NEGATIVE FOR MALIGNANCY.

BREAST CANCER PROGNOSTIC SUMMARY

SITE:	LEFT BREAST
TUMOR SIZE:	6.5 CM (ESTIMATED FROM SPECIMENS 4 AND 5)
TUMOR TYPE:	INFILTRATING LOBULAR CARCINOMA
HISTOLOGIC GRADE:	WELL DIFFERENTIATED
MODIFIED BLOOM-RICHARDSON SCORE:	5/9 (DUCT FORMATION 3, NUCLEAR GRADE 1, MITOTIC ACTIVITY 1)
IN SITU CARCINOMA:	PRESENT
TYPE:	LOBULAR, WITH ANTEGRADE DUCTAL INVOLVEMENT
EXTENSIVE IN SITU CARCINOMA:	NOT IDENTIFIED
MARGINS OF RESECTION:	POSITIVE: CARCINOMA INVOLVES MULTIPLE MARGINS OF THE
INITIAL	SEGMENT, MULTIPLE MARGINS OF THE ADDITIONAL SEGMENT,

[page 5 of 5]
AND THE
LATERAL

BIOPSIES OF INFERIOR MARGIN, SUPERIOR MARGIN AND
MARGIN.

NIPPLE/SKIN INVOLVEMENT: NOT APPLICABLE
LYMPHOVASCULAR INVASION: PRESENT
LYMPH NODES: POSITIVE
POSITIVE/TOTAL COUNT: 3 OUT OF 5
SENTINEL NODE: 3 OUT OF 4 SENTINEL NODES
TNM PATHOLOGIC STAGE: pT3 N1a MX
MOLECULAR STUDIES: PARAFFIN BLOCK 4E

Signed Electronically signed by:

** END OF REPORT **

Source: NCI Genomic Data Commons file 9a0f9257-033a-43c0-91ff-43b08db76561 (TCGA-Z7-A8R5.7726F7AA-88A8-4DD6-B322-6FC68893E0D2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).